FM case AD3416 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/397343b1-870f-4b54-90a5-7c5767a0d683

Female, 52.5 years: Adenocarcinoma, diffuse type (ICD-O-3 8145/3) of the stomach; metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
